Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-A8B9, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-A8B9-TTP1-D (Primary Tumor).

[page 1 of 2]
CDDP-YP-A889-01-PR

Material: 1.upper lobar lymph nodes (12) 2.upper lobar lymph nodes (12) 3.left lung 4.lower lobar lymph nodes (12) 5. subaortic or duct lymph nodes (5)

Macro Description: 1.reddish 6 mm fragment.

2.brownish-red fragments, the largest 1 cm.

3.15 cm lung lobe with area of pleural retraction corresponding to, when cut, a 1.8 cm diameter, grayish, irregular area with ill-defined margins.

4.1 cm brownish fragment.

5.1 cm reddish fragment

Micro Description: 1.3 small anthracotic lymph nodes are isolated.

2.4 reactive anthracotic lymph nodes are isolated.

3.Mixed adenocarcinoma with aspects both of the papillary type and bronchioloalveolar mucosecreting type, infiltrating but not going beyond the pleura.Bronchial resection margin free of neoplasia.

Atelectasis of remaining parenchyma.

4.one anthracotic lymph node isolated.

5.2 anthracotic lymph nodes isolated.

Stage: -

Report 2:

Date Report 2:

Material 2:

Macro Description 2:

Notes:

ICDO Code: 82553

ICDO Description: Adenocarcinoma with mixed subtypes

Status: OK

Other Info:

ICD-0-3

adenocarcinoma w/ mixed subtypes 8255/3

site: ① lung, NOS C34.9

ICD-10

C34.92

hw
2/10/16

[page 2 of 2]
Material: 1.upper lobar lymph nodes (12) 2.upper lobar lymph nodes (12) 3.left lung 4.lower lobar lymph nodes (12) 5. subaortic or duct lymph nodes (5)

Macro Description: 1.reddish 6 mm fragment.

2.brownish-red fragments, the largest 1 cm.

3.15 cm lung lobe with area of pleural retraction corresponding to, when cut, a 1.8 cm diameter, grayish, irregular area with ill-defined margins.

4.1 cm

Micro Description: 1.3 small anthracotic lymph nodes are isolated.

2.4 reactive anthracotic lymph nodes are isolated.

3.Mixed adenocarcinoma with aspects both of the papillary type and bronchioloalveolar mucosecreting type, infiltrating but not going beyond the pleura.

Virtual Microscope: Adeno CA, papill, mod diff

Real Microscope: Mod diff adeno ca

Slide Quality: 4

Stage: -

cT	cN	cM	cStage	cGrading
2	0	0	IB	X

pT	pN	pM	pStage	pGrading
2	0	0	IB	X

Report 2:

Report Date 2:

Material 2:

Criteria	hw 2/10/16	Yes	No

Source: NCI Genomic Data Commons file 6d167043-bd3f-4ca8-9120-9406b0fcad56 (CDDP-A8B9-TTP1.A7640E0F-B266-4982-B3F4-E62F89A2B66B.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).